Somatic mutation profile of tumor specimen TCGA-BP-4998-01A (aliquot TCGA-BP-4998-01A-01D-1462-08) from TCGA case TCGA-BP-4998, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 49.3 years (17,997 days).
Specimen TCGA-BP-4998-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31658481-3f15-4019-845a-1266460fbaf4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4998-11A (Solid Tissue Normal), aliquot TCGA-BP-4998-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba524368-7e0c-4a1c-84ff-7b36343283c2

The open-access MAF lists 36 somatic variants for this specimen: 29 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 6, Nonsense Mutation 2, Frame Shift Del 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALAS1 | c.224T>C p.V75A | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1321438354, COSV59629630; called by muse, mutect2, varscan2
- BRCA1 | c.5492C>T p.P1831L | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as CD992736, COSV58799506; called by muse, mutect2, varscan2
- C3 | c.4339T>C p.Y1447H | Missense Mutation (SNP) | VAF 65/270 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55581342; called by muse, mutect2, varscan2
- C6orf62 | c.333G>A p.M111I | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV65291162; called by muse, mutect2, varscan2
- CENPJ | c.3027T>A p.D1009E | Missense Mutation (SNP) | VAF 49/288 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV67884261; called by muse, mutect2, varscan2
- COL6A2 | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.392); catalogued as rs781676156, COSV56015920; called by muse, mutect2, varscan2
- IRF2BP2 | c.1400G>T p.R467I | Missense Mutation (SNP) | VAF 56/233 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV64015657; called by muse, mutect2, varscan2
- KNG1 | c.1505G>A p.G502D | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.063); catalogued as COSV53980995; called by muse, mutect2
- LRP11 | c.771+1G>T p.X257_splice | Splice Site (SNP) | VAF 16/98 reads (16%) | catalogued as rs1354742224, COSV53335455; called by muse, mutect2, varscan2
- NBEAL2 | c.5132G>A p.R1711H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs1272526590, COSV52754420; called by muse, mutect2
- NKAIN3 | c.104C>G p.A35G | Missense Mutation (SNP) | VAF 45/215 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as rs746522619, COSV60657914, COSV60684492; called by muse, mutect2, varscan2
- NPHP1 | c.1081G>A p.A361T (on ENST00000393272 / NM_207181.4; = p.A362T on NM_000272.5) | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV57211725; called by muse, mutect2, varscan2
- OSBP | c.1554A>C p.E518D | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55665718; called by muse, mutect2, varscan2
- PGPEP1 | c.196A>G p.S66G | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs768262854, COSV53253002; called by muse, mutect2, varscan2
- PHF3 | c.3710A>G p.E1237G | Missense Mutation (SNP) | VAF 53/256 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50341500; called by muse, mutect2, varscan2
- PPP1R3A | c.13G>T p.E5* | Nonsense Mutation (SNP) | VAF 22/146 reads (15%) | catalogued as COSV52893059; called by muse, mutect2, varscan2
- QPCT | c.364A>G p.N122D | Missense Mutation (SNP) | VAF 5/112 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV58121302; called by muse, mutect2
- REM1 | c.112T>G p.S38A | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV52430112; called by muse, mutect2, varscan2
- RPLP0 | c.293T>G p.I98S | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV56114729; called by muse, mutect2, varscan2
- RREB1 | c.2030A>T p.D677V | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58565396; called by muse, mutect2, varscan2
- SLC12A6 | c.1165G>A p.V389I (on ENST00000354181 / NM_001365088.1; = p.V338I on NM_005135.2) | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs766616549, COSV51631954; called by muse, mutect2, varscan2
- SLC4A10 | c.918A>C p.E306D | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV55790366; called by muse, mutect2, varscan2
- SNX17 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as rs377585045; called by muse, mutect2, varscan2
- TDRD6 | c.1553G>T p.R518M | Missense Mutation (SNP) | VAF 52/197 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV60178615; called by muse, varscan2
- TTN | c.14951T>A p.L4984* (on ENST00000591111; = p.L4057* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 20/208 reads (10%) | catalogued as COSV60345524; called by muse, mutect2
- VHL | c.458T>C p.L153P | Missense Mutation (SNP) | VAF 57/231 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM114591, COSV56543809, COSV56552902, COSV56558571; called by muse, mutect2, varscan2
- WNT10A | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs748131786, COSV51461426; called by muse, mutect2, varscan2
- ZAN | c.2666T>C p.I889T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs113151628; called by muse, varscan2
- PRRC2C | c.4178_4182del p.P1393Qfs*3 (on ENST00000367742; = p.P1391Qfs*3 on NM_015172.4) | Frame Shift Del (DEL) | VAF 7/43 reads (16%) | called by mutect2, pindel, varscan2
- ABL1 | c.3198C>T p.F1066= | Silent (SNP) | VAF 28/113 reads (25%) | catalogued as COSV59341101; called by muse, mutect2, varscan2
- CFAP94 | c.1692T>A p.A564= (on ENST00000320267 / NM_001352064.2; = p.A570= on NM_018272.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/193 reads (21%) | catalogued as COSV57236757; called by muse, mutect2, varscan2
- CTRC | c.549C>T p.H183= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as rs554399153, COSV65622007; ClinVar: likely benign; called by muse, mutect2, varscan2
- PARP12 | c.1917C>G p.A639= | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as COSV54937150; called by muse, mutect2, varscan2
- PHF8 | c.375A>G p.R125= (on ENST00000357988 / NM_001184896.1; = p.R89= on NM_015107.3) | Silent (SNP) | VAF 48/106 reads (45%) | catalogued as COSV57687897; called by muse, mutect2, varscan2
- SRRM2 | c.6753A>T p.P2251= | Silent (SNP) | VAF 33/145 reads (23%) | catalogued as COSV51941911; called by muse, mutect2, varscan2
- USP17L30 | chr4:9359265 G>T | 5'Flank (SNP) | VAF 8/316 reads (3%) | called by muse, mutect2
